Somatic mutation profile of tumor specimen BA2047D (aliquot aq-BA2047D) from BEATAML1.0 case 2467, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,349 days).
Specimen BA2047D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f757053d-2aaa-4168-a5fb-5a04a6ad095e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2874D (Solid Tissue Normal), aliquot aq-BA2874D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc6ec8ab-f47c-4b31-9caf-5d9f58a2d79b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZFYVE28 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.113); catalogued as COSV99342390; called by muse, mutect2
- OR6M1 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBC1D14 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- LZTS1 | c.1362G>T p.L454= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- USP11 | c.16C>A p.R6= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
